Somatic mutation profile of tumor specimen 0DV5SF from CCDI case PBCMGT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Carcinoma, metastatic, NOS; Tissue or organ of origin: Endometrium; Age at diagnosis: 15.8 years (5,786 days).
Specimen 0DV5SF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c429e78-3856-4770-91e4-07ebc8082dbd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV5RU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d190d282-fc1c-45fa-b4bd-cb7fdb61a76a

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL645922.1 | c.3542G>A p.R1181Q | Missense Mutation (SNP) | VAF 23/468 reads (5%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.55); catalogued as rs527879781; called by muse, mutect2
- DNAJC10 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 39/401 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.557); catalogued as rs1168216180; called by muse, mutect2
- MRPS31 | c.505G>C p.D169H | Missense Mutation (SNP) | VAF 62/801 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60266292, COSV60268579; called by muse, mutect2
- OR51I2 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 35/720 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as rs780180209; called by muse, mutect2
- SRGAP3 | c.2629C>T p.R877W | Missense Mutation (SNP) | VAF 25/371 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV100841265, COSV64535117; called by muse, mutect2
- TLR2 | c.2317G>A p.G773R | Missense Mutation (SNP) | VAF 34/760 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.038); catalogued as COSV52607427; called by muse, mutect2
- WNT11 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 23/420 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.357); catalogued as rs1046121955, COSV59443551; called by muse, mutect2
- WWTR1 | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100640965; called by muse, mutect2, varscan2
- CENPE | c.1785G>C p.Q595H | Missense Mutation (SNP) | VAF 35/690 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- CEP170 | c.1806G>C p.R602S | Missense Mutation (SNP) | VAF 26/818 reads (3%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2
- DERL1 | c.238T>G p.Y80D | Missense Mutation (SNP) | VAF 38/692 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OTOP1 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 17/309 reads (6%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2
- RANBP10 | c.280C>G p.H94D | Missense Mutation (SNP) | VAF 74/650 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- TAF7 | c.1016T>G p.L339W | Missense Mutation (SNP) | VAF 37/611 reads (6%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- TIPRL | c.574G>C p.V192L | Missense Mutation (SNP) | VAF 36/766 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF287 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 46/486 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); called by muse, mutect2
- ZNF831 | c.4278C>G p.C1426W | Missense Mutation (SNP) | VAF 28/698 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.118); called by muse, mutect2
- FGD1 | c.1323G>A p.E441= | Silent (SNP) | VAF 35/552 reads (6%) | called by muse, mutect2
- SEZ6L | c.396G>A p.L132= | Silent (SNP) | VAF 23/410 reads (6%) | called by muse, mutect2
- TIMM22 | c.84C>T p.L28= | Silent (SNP) | VAF 15/350 reads (4%) | catalogued as rs151141280; called by muse, mutect2
- GRB10 | c.52-6975C>T | Intron (SNP) | VAF 28/492 reads (6%) | catalogued as rs777726268; called by muse, mutect2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
